TCGA case TCGA-06-0676 — Glioblastoma Multiforme (TCGA-GBM)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Primary site: Brain; Tissue source site: Henry Ford Hospital.
https://portal.gdc.cancer.gov/cases/79c45580-bd0d-48c3-8f42-974c724a3835

Biospecimens (1 sample)
- Sample TCGA-06-0676-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Longest dimension: 0.8; Intermediate dimension: 0.7; Shortest dimension: 0.3.
